Somatic mutation profile of tumor specimen TCGA-55-6972-01A (aliquot TCGA-55-6972-01A-11D-1945-08) from TCGA case TCGA-55-6972, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.9 years (26,625 days).
Specimen TCGA-55-6972-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdd8cd2b-bd1f-402f-aab5-9e844d1afb1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6972-11A (Solid Tissue Normal), aliquot TCGA-55-6972-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3acb8ab8-4863-4b12-a02c-4e4ef7e38f84

The open-access MAF lists 287 somatic variants for this specimen: 216 protein-altering or splice-affecting, 66 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 66, Nonsense Mutation 19, Frame Shift Del 5, Splice Site 4, Intron 3, Frame Shift Ins 3, In Frame Del 2, Splice Region 1, Translation Start Site 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2522C>A p.A841E | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1416566507, COSV55958199; called by muse, mutect2, varscan2
- ABHD2 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV61775456; called by muse, mutect2, varscan2
- ACTG1 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs11549209, COSV59511395; called by muse, mutect2, varscan2
- ADAMTS19 | c.1474C>G p.H492D | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50773094; called by muse, mutect2, varscan2
- AJUBA | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1421672981, COSV52986201; called by muse, mutect2, varscan2
- AL592490.1 | c.1812G>C p.K604N | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV69427217; called by muse, mutect2, varscan2
- AMD1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV64387892; called by muse, mutect2, varscan2
- ANKRD27 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs199860219, COSV60134249; called by muse, mutect2, varscan2
- AOC1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs756074061, COSV62870077; called by muse, mutect2, varscan2
- AP5Z1 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs200224845; called by mutect2, varscan2
- ARHGAP25 | c.1834C>A p.R612S (on ENST00000409202 / NM_001007231.3; = p.R604S on NM_014882.3) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV54903744, COSV54905907; called by muse, mutect2, varscan2
- ARID4B | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51608228, COSV99935402; called by muse, mutect2
- ASXL2 | c.3242C>T p.S1081L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV55459122; called by muse, mutect2, varscan2
- ATN1 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as rs1555143286, COSV63112383; called by muse, mutect2, varscan2
- ATP13A4 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61323478; called by muse, mutect2, varscan2
- BBX | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as COSV57890635; called by muse, mutect2
- BDP1 | c.3452G>C p.R1151T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as COSV62433135; called by muse, mutect2, varscan2
- BOD1L1 | c.7853C>G p.S2618C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.533); catalogued as rs1351371191, COSV50034698; called by muse, mutect2, varscan2
- BRAT1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV61394086; called by muse, mutect2, varscan2
- BRCA1 | c.4643C>T p.T1548M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs273900737, COSV58788973; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- BRINP1 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); catalogued as COSV56307545, COSV56307711; called by muse, mutect2, varscan2
- BTNL2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs1208793009, COSV66631422; called by muse, mutect2
- C6orf118 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs138289053, COSV57813373; called by muse, mutect2, varscan2
- C6orf118 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV57817327; called by muse, mutect2, varscan2
- CAPN5 | c.1189G>C p.A397P (on ENST00000456580; = p.A357P on NM_004055.5) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV53690067; called by muse, mutect2, varscan2
- CATSPER2 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs756665870, COSV58660745, COSV58661444; called by muse, mutect2, varscan2
- CCDC80 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52818801; called by muse, mutect2, varscan2
- CCN5 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV51938485; called by muse, mutect2, varscan2
- CCSER1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393771, COSV61451381; called by muse, mutect2
- CDC7 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV52311926; called by muse, mutect2, varscan2
- CDYL | c.1717G>A p.V573M (on ENST00000328908 / NM_001368125.1; = p.V519M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs1193326779, COSV59360990; called by muse, mutect2, varscan2
- CELF2 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.091); catalogued as COSV64930189; called by muse, mutect2, varscan2
- CFAP46 | c.7328G>A p.R2443K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as COSV54156326; called by muse, mutect2
- CFH | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.771); catalogued as COSV66411289; called by muse, mutect2, varscan2
- CHODL | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54732677; called by muse, mutect2, varscan2
- CLCN5 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV56585791; called by muse, mutect2, varscan2
- CNTNAP2 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100663504, COSV62227448; called by muse, mutect2, varscan2
- COL4A2 | c.4738G>C p.E1580Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV64631592; called by muse, mutect2, varscan2
- COL6A3 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV55090419, COSV99040701; called by muse, mutect2, varscan2
- COL6A3 | c.2210G>C p.S737T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55100554; called by muse, mutect2
- COPS3 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs1271730785, COSV52006686; called by muse, mutect2, varscan2
- CPXM1 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs1440517943, COSV66046260; called by muse, mutect2, varscan2
- CSMD1 | c.10299C>G p.N3433K (on ENST00000520002; = p.N3432K on NM_033225.6) | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs775400212, COSV59356683; called by muse, mutect2, varscan2
- CSMD1 | c.5349G>C p.Q1783H (on ENST00000520002; = p.Q1782H on NM_033225.6) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.683); catalogued as rs754641625, COSV59356713; called by muse, mutect2, varscan2
- CSMD3 | c.10589C>A p.A3530E (on ENST00000297405 / NM_001363185.1; = p.A3361E on NM_052900.3) | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV52261015; called by muse, mutect2, varscan2
- CSPP1 | c.2299G>A p.E767K (on ENST00000676605; = p.E726K on NM_024790.6) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as COSV51589451; called by muse, mutect2, varscan2
- CUX1 | c.442G>A p.E148K (on ENST00000292535 / NM_181552.4; = p.E159K on NM_001913.5) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV52909140; called by muse, mutect2, varscan2
- DENND4C | c.950C>G p.S317* | Nonsense Mutation (SNP) | VAF 10/123 reads (8%) | catalogued as COSV66822229, COSV66822942; called by muse, mutect2
- DIDO1 | c.4751G>A p.R1584H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs372175100; called by mutect2, varscan2
- DIO1 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs764259068, COSV50778605; called by muse, mutect2, varscan2
- DLGAP2 | c.2326G>T p.A776S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); catalogued as rs1283667939, COSV70093658, COSV70101986; called by muse, mutect2, varscan2
- DMBT1 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 140/233 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV57553121; called by muse, mutect2, varscan2
- DNAH10 | c.6791C>G p.S2264C (on ENST00000409039; = p.S2203C on NM_207437.3) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68987684, COSV68998453; called by muse, mutect2
- DNAH10 | c.9101C>A p.S3034Y (on ENST00000409039; = p.S2973Y on NM_207437.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.36); catalogued as COSV68998458, COSV69000558; called by muse, mutect2, varscan2
- DNAH5 | c.3755A>G p.D1252G | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV54241698, COSV99451854; called by muse, mutect2, varscan2
- DNAH9 | c.12349C>A p.H4117N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52365414; called by muse, mutect2, varscan2
- DNM2 | c.1129-1G>C p.X377_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV58968048; called by muse, varscan2
- DOCK2 | c.2359A>T p.T787S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.68); PolyPhen benign (0.049); catalogued as COSV56975661; called by muse, mutect2, varscan2
- DSCC1 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV58087874; called by muse, mutect2, varscan2
- ECT2L | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62886151; called by muse, mutect2, varscan2
- EDAR | c.1078C>A p.L360I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51505873; called by muse, mutect2, varscan2
- EDIL3 | c.249C>A p.C83* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as COSV56911469, COSV99678478; called by muse, mutect2, varscan2
- ELF1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV53501278; called by muse, mutect2, varscan2
- ENDOD1 | c.1114A>G p.I372V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV53590726; called by muse, mutect2, varscan2
- EXOC8 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV50479012; called by muse, mutect2
- F5 | c.3355C>T p.Q1119* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as COSV63126271; called by muse, mutect2
- FAM183A | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58922925; called by mutect2, varscan2
- FCHO1 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV53184038; called by muse, mutect2, varscan2
- FGL1 | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1205932253, COSV67713115; called by muse, mutect2, varscan2
- FHOD3 | c.3802G>T p.A1268S (on ENST00000359247 / NM_001281739.3; = p.A1285S on NM_025135.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs571460399, COSV57181984; called by muse, mutect2, varscan2
- FMN2 | c.2725C>G p.P909A | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.265); catalogued as COSV100144587, COSV60443629; called by muse, mutect2, varscan2
- GALNT2 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1270941733, COSV64196548; called by muse, mutect2
- GPN3 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57399943; called by muse, mutect2, varscan2
- GRAP2 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 119/138 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59996383, COSV59996418; called by muse, mutect2, varscan2
- GRM3 | c.1563G>C p.M521I | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV64476671, COSV64479401; called by muse, mutect2, varscan2
- H2BC13 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV62441034; called by muse, mutect2, varscan2
- H3C3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as COSV63551301, COSV63551317; called by muse, mutect2, varscan2
- HIVEP1 | c.6464A>T p.D2155V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65103776; called by muse, mutect2, varscan2
- HLF | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56831233; called by muse, mutect2
- HUS1B | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750302587, COSV57869494; called by mutect2, varscan2
- ITGA10 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 27/345 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV65198470; called by muse, mutect2
- ITGB6 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as rs895833975, COSV51796967; called by muse, mutect2
- ITM2B | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV66035445, COSV66035646; called by mutect2, varscan2
- KAT14 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV66608684; called by muse, mutect2, varscan2
- KBTBD6 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.203); catalogued as COSV65271722, COSV65271771; called by muse, mutect2, varscan2
- KCNQ1 | c.681C>T p.I227= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as COSV50120948; called by muse, mutect2, varscan2
- KEAP1 | c.1708+2T>A p.X570_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | catalogued as COSV50565599; called by muse, mutect2, varscan2
- KMT2C | c.12463C>T p.P4155S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs771799416, COSV51476952; called by muse, mutect2
- LCP2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs1440505024, COSV50458944, COSV50471373; called by muse, mutect2, varscan2
- LECT2 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV50846904; called by muse, mutect2
- LMBR1 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV62222199; called by muse, mutect2, varscan2
- LRRC8D | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 25/30 reads (83%) | catalogued as COSV61580510; called by muse, mutect2, varscan2
- LRRIQ4 | c.940C>G p.H314D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.161); catalogued as rs1172560663, COSV61619828; called by muse, mutect2, varscan2
- LRRTM4 | c.943T>A p.C315S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69141190; called by muse, mutect2, varscan2
- LUC7L | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV53459845; called by muse, mutect2
- MDGA2 | c.1518C>A p.S506R (on ENST00000399232 / NM_001113498.2; = p.S208R on NM_182830.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV100638640, COSV62105937; called by muse, varscan2
- MDN1 | c.10699G>A p.E3567K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV65526668; called by muse, mutect2, varscan2
- MEI1 | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs1354407307, COSV55905566; called by muse, mutect2, varscan2
- METTL16 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54015299; called by muse, mutect2, varscan2
- MICB | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1374105414, COSV52857306; called by muse, mutect2, varscan2
- MINDY4 | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as COSV54676815; called by muse, mutect2, varscan2
- MTBP | c.2582T>A p.L861H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59965061; called by muse, mutect2, varscan2
- MTF2 | c.833G>T p.S278I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64771655; called by muse, mutect2, varscan2
- MTUS2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV70914305, COSV70920740; called by muse, mutect2, varscan2
- MUC5B | c.4418G>A p.S1473N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV71594329; called by muse, mutect2, varscan2
- MYB | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1443630742, COSV57200298; called by muse, mutect2, varscan2
- MYH4 | c.1374C>A p.Y458* | Nonsense Mutation (SNP) | VAF 50/133 reads (38%) | catalogued as COSV55123203; called by muse, mutect2, varscan2
- NAIF1 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV66091860; called by muse, mutect2, varscan2
- NAV3 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV57100136; called by muse, mutect2, varscan2
- NCKAP5 | c.5355C>A p.S1785R | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs751280659, COSV58435562, COSV58462958; called by muse, mutect2, varscan2
- NCOR2 | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62301469; called by muse, mutect2, varscan2
- NELL1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV54300005; called by muse, mutect2, varscan2
- NEUROD4 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.831); catalogued as COSV54472934, COSV54474437; called by muse, mutect2, varscan2
- NFKBID | c.615G>T p.K205N (on ENST00000396901; = p.K357N on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61729560; called by muse, mutect2, varscan2
- NKX2-8 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177558428, COSV51873037; called by muse, mutect2, varscan2
- NSUN3 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as rs1257324053, COSV58936917; called by muse, mutect2, varscan2
- NXF3 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV67704603; called by muse, mutect2, varscan2
- OBSCN | c.3172G>T p.G1058C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52805978; called by muse, mutect2, varscan2
- OR2T4 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 127/261 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV63544709; called by muse, mutect2, varscan2
- OR5D14 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV59455727, COSV59457599; called by muse, mutect2, varscan2
- OR5T3 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs534545230, COSV57381921; called by muse, mutect2, varscan2
- OR7C1 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.02); catalogued as COSV50183936; called by muse, mutect2, varscan2
- OR8K3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV100449944, COSV57132373; called by muse, mutect2, varscan2
- OSM | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV53161970; called by muse, mutect2, varscan2
- PAGE5 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56944122; called by muse, mutect2, varscan2
- PANX1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57134551; called by muse, mutect2, varscan2
- PCDH15 | c.4810G>A p.E1604K | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated, low confidence (0.06); catalogued as COSV64717053; called by muse, mutect2, varscan2
- PCDH15 | c.2869G>T p.G957* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV57265314, COSV57360873; called by muse, mutect2, varscan2
- PCDH15 | c.1110C>A p.D370E | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.816); catalogued as rs1274139015, COSV57360903; called by muse, mutect2, varscan2
- PCDHA3 | c.1238T>A p.L413Q | Missense Mutation (SNP) | VAF 153/276 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63544421, COSV63546682; called by muse, mutect2, varscan2
- PCDHB8 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.05); catalogued as rs782643110, COSV50762098; called by muse, mutect2, varscan2
- PDE1C | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1437753806, COSV58522456; called by muse, mutect2, varscan2
- PDE6A | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54929863; called by muse, mutect2, varscan2
- PDZD7 | c.119C>A p.T40K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); catalogued as COSV56520228, COSV56520961; called by muse, varscan2
- PDZD8 | c.2125A>G p.R709G | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1378642954, COSV57827448; called by muse, mutect2, varscan2
- PIP4P1 | c.773T>G p.L258W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51658452; called by muse, mutect2, varscan2
- PLEKHS1 | c.943G>C p.E315Q (on ENST00000369310 / NM_182601.1; = p.E335Q on NM_024889.5) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63055121; called by muse, mutect2, varscan2
- PPM1L | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1214662234, COSV55568221; called by muse, mutect2, varscan2
- PPP1R10 | c.2260C>T p.H754Y | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1241716997, COSV64740010; called by muse, mutect2
- PRC1 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62696202; called by muse, mutect2, varscan2
- PRKAR2A | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV55553372; called by muse, mutect2
- PRKX | c.898C>G p.H300D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53325588; called by muse, mutect2
- PROS1 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD084192, COSV67776504; called by muse, mutect2, varscan2
- PROX1 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as rs961356080, COSV54781787; called by muse, mutect2, varscan2
- PTCHD3 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs766118465; called by muse, mutect2
- PTGIS | c.1488C>A p.Y496* | Nonsense Mutation (SNP) | VAF 31/54 reads (57%) | catalogued as COSV54839225; called by muse, mutect2, varscan2
- PYGM | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV51215711, COSV51223034; called by muse, mutect2, varscan2
- RBM34 | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs189294443, COSV100784040, COSV64013104; called by muse, mutect2, varscan2
- REG3A | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV59410786, COSV59412087; called by muse, mutect2, varscan2
- RIPPLY3 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV61566983; called by muse, mutect2, varscan2
- RNF20 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | catalogued as rs1456634288, COSV66355810; called by muse, mutect2, varscan2
- RPGRIP1L | c.231-1G>T p.X77_splice | Splice Site (SNP) | VAF 17/115 reads (15%) | catalogued as rs769036874, COSV50912250; called by muse, mutect2, varscan2
- RUSC2 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs767394239, COSV63429711; called by muse, mutect2, varscan2
- SALL1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1333226928, COSV51761696; called by muse, mutect2
- SASH1 | c.3472C>A p.R1158S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66558671, COSV66564030; called by muse, mutect2, varscan2
- SCRIB | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV57581841; called by muse, mutect2, varscan2
- SENP3 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53437018; called by muse, mutect2, varscan2
- SETBP1 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs936498551, COSV56330864; called by muse, mutect2, varscan2
- SH2B2 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60827245; called by muse, mutect2, varscan2
- SLC12A7 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53760223; called by muse, mutect2, varscan2
- SLC8A3 | c.2584G>A p.A862T (on ENST00000381269 / NM_183002.3; = p.A860T on NM_033262.4) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1389642553, COSV53691472; called by muse, mutect2, varscan2
- SMC1A | c.3386C>T p.S1129L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59131031; called by muse, mutect2, varscan2
- SNX19 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV56287643; called by muse, mutect2, varscan2
- SPAG17 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV60464198; called by muse, mutect2, varscan2
- SRL | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as COSV68424018; called by muse, mutect2, varscan2
- ST6GAL2 | c.871C>A p.R291S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | PolyPhen benign (0.078); catalogued as rs754052250, COSV64526128, COSV64528793; called by muse, mutect2, varscan2
- ST8SIA6 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 112/225 reads (50%) | catalogued as COSV101112212, COSV66470450; called by muse, mutect2, varscan2
- SULT1B1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1198812483, COSV60208691; called by muse, varscan2
- SULT1C4 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335766834, COSV55598495; called by muse, mutect2, varscan2
- SV2B | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57699182; called by muse, mutect2, varscan2
- SYN1 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV55983662; called by muse, mutect2, varscan2
- TLR7 | c.1806G>A p.M602I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV66125018, COSV66125316; called by muse, mutect2, varscan2
- TMEM259 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs766501808, COSV52262150; called by mutect2, varscan2
- TPX2 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as rs1424613527, COSV100301987, COSV55921342; called by muse, mutect2
- TRANK1 | c.6021C>G p.F2007L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57158766; called by muse, mutect2
- TRPC6 | c.2349G>T p.W783C | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV60258586; called by muse, mutect2, varscan2
- TUBB8 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV59117084; called by muse, mutect2
- USH1C | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50026356; called by muse, mutect2, varscan2
- YRDC | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV65990042; called by muse, mutect2
- ZBTB45 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1346572828, COSV63524816; called by muse, mutect2, varscan2
- ZNF225 | c.554T>G p.F185C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53472553; called by muse, mutect2, varscan2
- ZNF25 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56921658; called by muse, mutect2, varscan2
- ZNF292 | c.6357G>T p.Q2119H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60543861; called by muse, mutect2, varscan2
- ZNF536 | c.1995C>A p.H665Q | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100834775, COSV62830115; called by muse, mutect2, varscan2
- ZNF568 | c.1732A>G p.R578G | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1307671034, COSV61742418; called by muse, mutect2, varscan2
- ZNF654 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV58806772; called by muse, mutect2, varscan2
- ZNF789 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV58874901; called by muse, mutect2, varscan2
- ZZEF1 | c.8315G>T p.G2772V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67559180; called by muse, mutect2, varscan2
- ALOX12B | c.1267del p.L423Sfs*44 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- CBWD5 | c.1058G>A p.R353K (on ENST00000382405 / NM_001330668.1; = p.R305K on NM_001024916.3) | Missense Mutation (SNP) | VAF 27/484 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CDH8 | c.577_600del p.D193_G200del | In Frame Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel
- CNOT6L | c.99dup p.S34Ifs*11 (on ENST00000504123 / NM_001286790.2; = p.S29Ifs*11 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 19/121 reads (16%) | called by mutect2, pindel, varscan2
- DDR2 | c.1275G>T p.W425C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DROSHA | c.2503A>T p.R835* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- DROSHA | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ECM2 | c.1205del p.G402Efs*4 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ENPP6 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCGBP | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, varscan2
- GRAMD1B | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- HNRNPH1 | c.823_828del p.R275_Y276del | In Frame Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel, varscan2
- HUNK | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGHV4-31 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- KCNH7 | c.977_995del p.Y326Ffs*6 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- KEL | c.546dup p.G183Wfs*2 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, varscan2
- KIR3DL1 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.258); called by muse, varscan2
- MYO3A | c.1419dup p.G474Wfs*9 | Frame Shift Ins (INS) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- OR8U1 | c.510C>A p.H170Q | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PRAMEF14 | c.252del p.L85Ffs*45 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- SPANXB1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 75/295 reads (25%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.1294G>T p.G432* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TAF1L | c.2147C>A p.A716E | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAS1R1 | c.985A>T p.R329W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, varscan2
- TPR | c.3399_3402del p.R1136Cfs*2 | Frame Shift Del (DEL) | VAF 28/273 reads (10%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 114/460 reads (25%) | called by muse, mutect2
- ZNF134 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- ABCC9 | c.1065A>T p.A355= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV53980215; called by muse, mutect2, varscan2
- ACO1 | c.960G>A p.L320= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as COSV59382870; called by muse, mutect2, varscan2
- ADGRB1 | c.3387G>A p.K1129= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV60101326; called by muse, mutect2, varscan2
- ALPK2 | c.705G>T p.V235= | Silent (SNP) | VAF 90/166 reads (54%) | catalogued as COSV64495126; called by muse, mutect2, varscan2
- ATP1B3 | c.147C>T p.F49= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV53951025; called by muse, mutect2, varscan2
- BCOR | c.1239A>T p.T413= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV60714089; called by muse, mutect2, varscan2
- CD300LG | c.978C>T p.F326= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1159754283; called by muse, mutect2, varscan2
- CDK10 | c.1002C>T p.L334= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1220805969, COSV57048164; called by muse, mutect2
- CHD7 | c.1614A>T p.A538= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV71113144; called by muse, varscan2
- CPA1 | c.402G>T p.L134= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV50572929; called by muse, mutect2, varscan2
- DNAH17 | c.8406G>T p.V2802= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs747869222; called by muse, mutect2, varscan2
- DNALI1 | c.687G>A p.V229= (on ENST00000296218; = p.V207= on NM_003462.5) | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- EDRF1 | c.771A>G p.E257= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV61765386; called by muse, mutect2, varscan2
- GALNT5 | c.135C>T p.I45= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV52039699; called by muse, mutect2, varscan2
- GNB1 | c.783C>T p.L261= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV66100565; called by muse, mutect2, varscan2
- GPAA1 | c.570G>C p.L190= | Silent (SNP) | VAF 68/124 reads (55%) | catalogued as rs782756116, COSV60156254; called by muse, mutect2, varscan2
- GPR35 | c.291G>A p.L97= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV60578167; called by mutect2, varscan2
- GRIN2C | c.1536C>T p.I512= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV53116301; called by muse, mutect2, varscan2
- H1-4 | c.459G>A p.K153= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs759116050, COSV56801533, COSV56803168; called by muse, mutect2
- HRNR | c.1041C>A p.G347= | Silent (SNP) | VAF 115/196 reads (59%) | catalogued as COSV64260997; called by muse, mutect2, varscan2
- ICA1 | c.693A>T p.L231= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV55581919; called by muse, mutect2, varscan2
- INSR | c.2190G>A p.K730= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV57169246; called by muse, mutect2, varscan2
- ITGB4 | c.2490G>A p.E830= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs749606058, COSV52322713; called by muse, mutect2
- ITIH1 | c.2577G>T p.V859= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV56257220; called by muse, mutect2, varscan2
- JAKMIP2 | c.36C>T p.P12= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs1212735856, COSV54610990; called by muse, mutect2, varscan2
- KIAA1755 | c.3201C>A p.R1067= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs769676534, COSV54079017; called by muse, mutect2, varscan2
- KRTAP10-6 | c.420C>T p.S140= | Silent (SNP) | VAF 83/108 reads (77%) | catalogued as rs782814622, COSV59972628; called by muse, mutect2, varscan2
- LHX5 | c.240C>T p.A80= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV55663692; called by muse, mutect2, varscan2
- LPO | c.1600C>T p.L534= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV51861160; called by muse, mutect2, varscan2
- MAP3K21 | c.2217C>T p.L739= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV64042267; called by muse, mutect2
- MBIP | c.231A>G p.Q77= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs761819183, COSV59254823; called by muse, mutect2, varscan2
- MDC1 | c.4206G>A p.K1402= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as COSV64526163; called by muse, mutect2, varscan2
- MITF | c.1516C>A p.R506= (on ENST00000448226 / NM_006722.3; = p.R406= on NM_000248.4) | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV58832734, COSV58834008; called by muse, mutect2, varscan2
- MSR1 | c.33G>A p.Q11= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV50521391; called by muse, mutect2, varscan2
- MTFR1L | c.447T>C p.D149= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs771090205, COSV65356289; called by muse, mutect2
- MYLK2 | c.1362G>A p.V454= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs1420598747, COSV65659651; called by muse, mutect2, varscan2
- NBEAL2 | c.3075C>T p.F1025= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52761362; called by muse, mutect2, varscan2
- NFKBIZ | c.1971C>A p.A657= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV58199455, COSV58201385; called by muse, mutect2, varscan2
- NR4A3 | c.1120C>T p.L374= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV58245788, COSV58247057; called by muse, mutect2, varscan2
- OPRK1 | c.153C>G p.P51= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs754402306, COSV55571633, COSV55572629; called by muse, mutect2, varscan2
- OR2T11 | c.477C>A p.I159= | Silent (SNP) | VAF 89/157 reads (57%) | catalogued as COSV58186478, COSV58186670; called by muse, mutect2, varscan2
- OR2T34 | c.648C>T p.I216= | Silent (SNP) | VAF 155/508 reads (31%) | catalogued as rs1402043187, COSV60901329; called by muse, mutect2, varscan2
- OR8B12 | c.798C>A p.P266= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV60912342; called by muse, mutect2, varscan2
- P4HA2 | c.1287G>A p.P429= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs141851075; called by muse, mutect2, varscan2
- PCDH19 | c.3099G>A p.L1033= (on ENST00000373034 / NM_001184880.2; = p.L985= on NM_020766.3) | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV55268302; called by muse, mutect2, varscan2
- PCDHB3 | c.130T>C p.L44= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV50603343; called by muse, mutect2, varscan2
- PCDHB8 | c.1083G>T p.A361= | Silent (SNP) | VAF 82/261 reads (31%) | catalogued as COSV50796815, COSV99177355; called by muse, mutect2, varscan2
- PCSK5 | c.1215T>C p.F405= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV65093432; called by muse, mutect2, varscan2
- PGBD2 | c.861G>A p.G287= | Silent (SNP) | VAF 22/213 reads (10%) | catalogued as COSV61400721; called by muse, mutect2, varscan2
- POLQ | c.564C>T p.V188= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs774704896, COSV51750150, COSV51757815; called by muse, mutect2, varscan2
- RASGRP1 | c.789C>T p.L263= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV60366682; called by muse, mutect2
- RSAD1 | c.1038G>A p.L346= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs1049484458, COSV51956540; called by muse, mutect2, varscan2
- RYR2 | c.12732C>A p.A4244= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV63678722, COSV63702163; called by muse, mutect2, varscan2
- SCN2B | c.264T>C p.I88= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54051504; called by muse, mutect2, varscan2
- SLC39A6 | c.693G>T p.R231= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as COSV52370471; called by muse, mutect2, varscan2
- SPATA6L | c.99C>T p.L33= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs186090330, COSV56305078; called by mutect2, varscan2
- STARD6 | c.216T>C p.I72= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV57143021; called by muse, mutect2, varscan2
- SV2A | c.1701G>A p.V567= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV64965470; called by muse, mutect2, varscan2
- TAF1L | c.2148A>T p.A716= | Silent (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- TRPV4 | c.1062C>T p.A354= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs115446386; ClinVar: likely benign; called by muse, mutect2, varscan2
- VWF | c.2607G>C p.T869= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs762512650, COSV54627260, COSV54628936, COSV99777823; called by muse, mutect2, varscan2
- WFDC10B | c.165A>G p.E55= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV57914480; called by muse, mutect2
- ZNF804B | c.1752C>T p.L584= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV60842813; called by muse, mutect2, varscan2
- ZSCAN20 | c.1140C>T p.V380= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as COSV63683852; called by muse, varscan2
- ZSCAN20 | c.1380C>T p.V460= | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as COSV63683859; called by muse, varscan2
- ZSCAN20 | c.1431C>T p.F477= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as rs372234933; called by muse, varscan2
- AL353804.4 | chrX:73824622 C>A | 5'Flank (SNP) | VAF 14/16 reads (88%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1806G>A | 3'UTR (SNP) | VAF 14/90 reads (16%) | catalogued as rs146389619; called by muse, mutect2, varscan2
- OGG1 | c.948+20del | Intron (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- PKM | c.1141-485C>T | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as COSV58790691; called by muse, mutect2, varscan2
- RIMS2 | c.698+53026G>T | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as COSV51656987; called by muse, mutect2, varscan2
